Gene-level copy-number profile of tumor specimen TCGA-DX-A7EF-01A from TCGA case TCGA-DX-A7EF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-A7EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.50c5baaa-298c-4340-82d9-714a27b2c093.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A7EF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8856efdf-04e1-404e-b60f-89ed73077b2e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 2: 3,269; copy number 3: 5,462; copy number 4: 17,812; copy number 5: 9,976; copy number 6: 14,360; copy number 7: 3,467; copy number 8: 3,281; copy number 9: 964; copy number 10: 294; copy number 11: 21; copy number 12: 245; copy number 13: 189; copy number 14: 123; copy number 15: 10; copy number 16: 30; copy number 18: 14; copy number 19: 84; copy number 20: 59; copy number 26: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A7EF-01A-11D-A33D-01): tumor purity 0.7, ploidy 4.96, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–4): FOCAD.
- chr9:20,786,927–31,381,490, 130 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,046 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,228,682–59,810,647, 22 genes, copy number 18–20 (within-gene range 6–20): AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711.
- chr1:81,208,568–81,252,096, 3 genes, copy number 9: AL357632.1, AC093154.1, RN7SKP247.
- chr1:81,426,456–81,506,296, 3 genes, copy number 9: HNRNPA3P14, ARID3BP1, AL138799.1.
- chr2:12,411,398–14,992,066, 17 genes, copy number 9: RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1.
- chr2:39,786,453–41,731,611, 9 genes, copy number 9: SLC8A1-AS1, AC007253.1, SLC8A1, AC007877.1, AC007317.1, AC007317.2, LINC01794, HNRNPA1P57, AC009413.1.
- chr2:49,563,388–53,970,993, 37 genes, copy number 9 (within-gene range 8–9): AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4.
- chr4:171,812,254–173,659,696, 21 genes, copy number 9 (within-gene range 4–9): GALNTL6, AC108064.1, AC105285.1, RN7SL253P, GALNT7, MIR548T, AC097534.1, HMGB2, SAP30-DT, SAP30, SCRG1, AC093849.4, RPL5P11, AC093849.3, RNU6-1096P, AC093849.1, AC093849.2, HAND2, HAND2-AS1, MORF4, RANP6.
- chr5:2,712,591–2,967,955, 7 genes, copy number 10: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2.
- chr5:6,827,853–7,391,907, 17 genes, copy number 9–12: MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:7,830,378–8,157,788, 9 genes, copy number 12: C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1.
- chr5:10,652,211–12,804,363, 12 genes, copy number 10 (within-gene range 8–15): AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194.
- chr5:13,690,331–14,532,128, 4 genes, copy number 12 (within-gene range 8–12): DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:23,951,348–29,600,868, 63 genes, copy number 12–19 (broad region; genes not listed).
- chr5:30,248,350–31,066,132, 6 genes, copy number 9–12: HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1.
- chr5:35,617,844–36,347,157, 19 genes, copy number 9: SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1.
- chr5:37,939,365–44,066,731, 110 genes, copy number 10–16 (broad region; genes not listed).
- chr5:50,396,192–54,737,057, 60 genes, copy number 9–10 (within-gene range 8–10): EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2.
- chr5:58,969,038–60,522,120, 5 genes, copy number 10 (within-gene range 7–10): PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582.
- chr5:60,751,791–61,304,811, 10 genes, copy number 9 (within-gene range 7–9): ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1, NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057.
- chr5:61,347,126–61,391,871, 3 genes, copy number 9: AC122718.2, AC122718.1, RPL3P6.
- chr7:63,011,463–64,375,584, 85 genes, copy number 10 (broad region; genes not listed).
- chr7:69,026,433–69,174,450, 3 genes, copy number 13: AC104688.1, RNU6-832P, AC069280.2.
- chr7:73,861,159–74,289,286, 10 genes, copy number 10: TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, AC005081.1.
- chr7:79,335,780–79,471,208, 4 genes, copy number 10: AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3.
- chr7:84,847,877–84,940,256, 4 genes, copy number 9–10: AC093716.1, HMGN2P11, AC074183.2, AC074183.1.
- chr7:104,328,700–112,521,670, 109 genes, copy number 14–18 (broad region; genes not listed).
- chr7:115,503,367–116,508,541, 14 genes, copy number 16: POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP.
- chr7:120,141,016–121,441,261, 18 genes, copy number 10–16 (within-gene range 8–16): AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2.
- chr7:122,849,746–129,430,211, 127 genes, copy number 12–14 (within-gene range 8–14) (broad region; genes not listed).
- chr7:132,648,794–142,345,985, 189 genes, copy number 13–26 (broad region; genes not listed).
- chr8:53,493,523–56,559,823, 62 genes, copy number 9 (broad region; genes not listed).
- chr9:32,979,560–43,045,120, 356 genes, copy number 9–13 (broad region; genes not listed).
- chr15:52,885,595–52,886,470, 1 gene, copy number 9: RPSAP55.
- chr15:55,746,639–55,746,767, 1 gene, copy number 9: AC009997.1.
- chr15:57,246,960–57,247,893, 1 gene, copy number 9: HNRNPA3P11.
- chr15:60,634,503–60,765,625, 6 genes, copy number 9: AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1.
- chr15:61,181,249–61,635,449, 3 genes, copy number 9 (within-gene range 3–9): AC012404.1, AC012404.2, AC104574.2.
- chr15:61,729,765–62,844,631, 24 genes, copy number 9 (within-gene range 3–9): LINC02349, AC009554.1, VPS13C, AC009554.2, AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1, MIR190A.
- chr17:52,390,515–55,173,632, 22 genes, copy number 9 (within-gene range 8–9): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4.
- chr18:43,115,747–80,247,514, 566 genes, copy number 9–10 (within-gene range 7–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
